Somatic mutation profile of tumor specimen TCGA-56-7823-01B (aliquot TCGA-56-7823-01B-11D-2244-08) from TCGA case TCGA-56-7823, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.4 years (21,344 days).
Specimen TCGA-56-7823-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b931e808-9d97-4e3a-b9c2-27aa22ac0357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7823-10A (Blood Derived Normal), aliquot TCGA-56-7823-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343a26d8-0803-495b-99fb-4e013db20dc5

The open-access MAF lists 307 somatic variants for this specimen: 225 protein-altering or splice-affecting, 68 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 68, Nonsense Mutation 12, Frame Shift Del 9, Splice Site 7, Intron 6, RNA 4, Frame Shift Ins 2, 3'UTR 2, Translation Start Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 19/21 reads (90%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCA1 | c.6755A>G p.Q2252R | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV101037299; called by muse, mutect2, varscan2
- ABCB1 | c.3364C>A p.L1122M | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55945215, COSV99713533; called by muse, mutect2, varscan2
- ABCB1 | c.1250T>A p.V417E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99713537; called by muse, mutect2, varscan2
- ADAD1 | c.1293A>G p.I431M | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV99635951; called by muse, mutect2, varscan2
- ADAM28 | c.1281+2T>C p.X427_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99739205; called by muse, mutect2
- ADAMTS7 | c.796T>A p.Y266N | Missense Mutation (SNP) | VAF 203/482 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101183170; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 124/278 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99647592; called by muse, mutect2, varscan2
- ADCY4 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100156691; called by muse, mutect2, varscan2
- AHCTF1 | c.5331A>T p.R1777S (on ENST00000366508; = p.R1751S on NM_015446.5) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100404052; called by mutect2, varscan2
- AHSG | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.062); catalogued as rs770692906, COSV99890160; called by muse, mutect2, varscan2
- AKAP4 | c.1925C>A p.P642H | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.754); catalogued as COSV100654316; called by muse, mutect2, varscan2
- ALOX5 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 84/135 reads (62%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100980114; called by muse, mutect2, varscan2
- ANK1 | c.4334A>T p.E1445V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99225912; called by muse, mutect2, varscan2
- ANKIB1 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV99729448; called by muse, mutect2, varscan2
- ANKRD11 | c.5330A>T p.Q1777L | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV99970007; called by muse, mutect2, varscan2
- ANO5 | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100202010; called by muse, mutect2, varscan2
- ASH2L | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.971); catalogued as COSV99167007; called by muse, mutect2, varscan2
- ATP11C | c.834A>T p.Q278H | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV100558255; called by muse, varscan2
- ATP13A4 | c.3540A>T p.R1180S | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100710497; called by muse, mutect2, varscan2
- ATP2B3 | c.2917T>C p.F973L | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99685145; called by muse, mutect2, varscan2
- BCL6 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1381617645, COSV99215851; called by muse, mutect2
- BCL9L | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV99419665; called by muse, varscan2
- BPIFB2 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99401529; called by muse, mutect2, varscan2
- BPNT1 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435735; called by muse, mutect2, varscan2
- BRD1 | c.1990A>T p.R664W | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99349996; called by muse, mutect2, varscan2
- BRINP2 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as rs370209121; called by muse, mutect2, varscan2
- BTD | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100329676; called by muse, mutect2, varscan2
- BTN3A3 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.833); catalogued as COSV99764951; called by muse, mutect2, varscan2
- CACNA1A | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100802804; called by muse, mutect2, varscan2
- CACNA1C | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100220126; called by muse, mutect2, varscan2
- CACNA1C | c.1597C>A p.L533M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100220129; called by mutect2, varscan2
- CACNG3 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867196696, COSV50068506; called by muse, mutect2, varscan2
- CAPN9 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55233552, COSV99680735; called by muse, mutect2, varscan2
- CCBE1 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV101232849; called by muse, mutect2, varscan2
- CCDC191 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as rs147633710; called by muse, mutect2, varscan2
- CCR1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs200503639, COSV99946755; called by muse, mutect2, varscan2
- CD28 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs199549636, COSV60731381; called by muse, mutect2, varscan2
- CDH10 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV100052185; called by muse, mutect2, varscan2
- CDH19 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100051862; called by muse, mutect2, varscan2
- CEP126 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV99681217; called by muse, mutect2, varscan2
- CHTF18 | c.2867G>T p.R956L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50211109; called by muse, mutect2, varscan2
- CIT | c.5879G>T p.R1960L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV99949344, COSV99950240; called by muse, mutect2, varscan2
- COL1A2 | c.1999G>C p.G667R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99800361; called by muse, mutect2, varscan2
- COL4A4 | c.2924G>T p.G975V | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307278; called by muse, mutect2, varscan2
- COL9A1 | c.2355C>A p.D785E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.03); catalogued as COSV100295127; called by muse, mutect2, varscan2
- CREB3L3 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99314305; called by muse, mutect2, varscan2
- CSMD3 | c.9515G>T p.S3172I (on ENST00000297405 / NM_001363185.1; = p.S3003I on NM_052900.3) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99839684; called by muse, mutect2, varscan2
- CSMD3 | c.6254A>G p.Q2085R (on ENST00000297405 / NM_001363185.1; = p.Q1981R on NM_052900.3) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99839689; called by muse, mutect2, varscan2
- CSMD3 | c.5570C>G p.P1857R (on ENST00000297405 / NM_001363185.1; = p.P1753R on NM_052900.3) | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.936); catalogued as COSV99839694; called by muse, mutect2, varscan2
- CTAGE6 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs536781747, COSV69917213; called by muse, mutect2, varscan2
- CXorf21 | c.552C>G p.Y184* | Nonsense Mutation (SNP) | VAF 35/45 reads (78%) | catalogued as COSV100973323; called by muse, mutect2, varscan2
- CYFIP2 | c.3277C>G p.P1093A (on ENST00000616178 / NM_001291722.2; = p.P1068A on NM_014376.4) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.959); catalogued as COSV100557368, COSV59047306; called by muse, mutect2, varscan2
- CYLC2 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100872494, COSV66338506; called by muse, mutect2, varscan2
- DACT1 | c.2162C>G p.A721G | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs372275201, COSV100241965; called by muse, mutect2, varscan2
- DCAF12L1 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100948368; called by muse, mutect2, varscan2
- DCAF4L2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60478085; called by muse, mutect2, varscan2
- DCDC1 | c.2363C>A p.T788K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.436); catalogued as COSV100663797; called by muse, mutect2, varscan2
- DMD | c.10633A>G p.M3545V | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as COSV100628241; called by muse, mutect2, varscan2
- DNMT3A | c.2174A>T p.E725V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99263282; called by muse, mutect2, varscan2
- DPYSL5 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99982556; called by muse, mutect2, varscan2
- DUSP2 | c.768C>A p.H256Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99997130; called by muse, mutect2, varscan2
- ENPP3 | c.905T>A p.L302Q | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100717671; called by muse, mutect2, varscan2
- EPSTI1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 68/77 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV100553054; called by muse, mutect2, varscan2
- F13A1 | c.1639C>A p.R547S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs767358574, COSV53553578, COSV99343451; called by muse, mutect2, varscan2
- FBXW7 | c.1789G>T p.G597W (on ENST00000281708 / NM_001349798.2; = p.G517W on NM_018315.5) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658783; called by muse, mutect2, varscan2
- FCGR2A | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99615544; called by muse, mutect2, varscan2
- G6PC | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 185/406 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99520891; called by muse, mutect2, varscan2
- GALNT17 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100352524, COSV100354642; called by muse, mutect2, varscan2
- GALNT4 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100544357; called by muse, mutect2, varscan2
- GCN1 | c.7785G>T p.K2595N | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100325609; called by muse, mutect2, varscan2
- GLRA2 | c.81C>G p.C27W | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV99491334; called by muse, mutect2, varscan2
- GPD2 | c.368A>C p.Q123P | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100133424; called by muse, mutect2, varscan2
- GPHN | c.934G>T p.V312L (on ENST00000315266 / NM_001377519.1; = p.V345L on NM_020806.5) | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs774554831, COSV100016819; called by muse, mutect2, varscan2
- GPR171 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs199881811, COSV56379384; called by muse, mutect2, varscan2
- HEPACAM2 | c.1049C>A p.S350* (on ENST00000394468 / NM_001039372.4; = p.S338* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100506647; called by muse, mutect2, varscan2
- HOXD3 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1472704270, COSV50887168; called by muse, mutect2, varscan2
- HSD17B12 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99550845; called by muse, mutect2, varscan2
- HSD17B12 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99550848; called by muse, mutect2, varscan2
- HSPA12B | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV99654074; called by muse, mutect2, varscan2
- HTR5A | c.475A>G p.N159D | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); catalogued as rs1376269884, COSV99839825; called by muse, mutect2, varscan2
- HYDIN | c.15212C>A p.P5071H | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101125135; called by muse, mutect2, varscan2
- IDO1 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV53714294, COSV99503477; called by muse, varscan2
- IFNA16 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV101207075; called by muse, mutect2, varscan2
- IGHV3-21 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 147/297 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.566); catalogued as rs367946248; called by muse, varscan2
- IGKV3D-11 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1286119270; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1322A>G p.Q441R (on ENST00000485419 / NM_001197113.1; = p.Q365R on NM_014575.3) | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100541437; called by muse, mutect2, varscan2
- IRX2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs759628648, COSV100121632, COSV100121814; called by muse, mutect2, varscan2
- ITIH1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56259291; called by muse, mutect2, varscan2
- ITPKC | c.1459A>G p.M487V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99648924; called by muse, mutect2, varscan2
- KCNJ3 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as COSV99716136; called by muse, mutect2, varscan2
- KCNU1 | c.2609A>G p.N870S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV101299327; called by muse, mutect2, varscan2
- KIR3DL2 | c.68T>A p.M23K | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs1482939823, COSV99552180; called by muse, mutect2, varscan2
- LFNG | c.956A>T p.Q319L (on ENST00000222725 / NM_001040167.2; = p.Q190L on NM_002304.2) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as rs750531076, COSV99761859; called by muse, mutect2, varscan2
- LRFN5 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV99984601; called by muse, mutect2, varscan2
- LRP1B | c.4783A>T p.N1595Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101258036; called by muse, mutect2, varscan2
- LRRCC1 | c.2194A>T p.K732* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100835506; called by muse, mutect2, varscan2
- LRRIQ1 | c.3213G>T p.L1071F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101280633; called by muse, mutect2, varscan2
- MCF2L | c.3050G>C p.S1017T (on ENST00000375608; = p.S985T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/734 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV99995955, COSV99996205; called by muse, mutect2, varscan2
- ME3 | c.1217T>A p.V406E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV100661024; called by muse, mutect2, varscan2
- MED13L | c.2554G>C p.V852L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV99929421; called by muse, mutect2, varscan2
- MED17 | c.1008T>G p.F336L | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV99316121; called by muse, mutect2, varscan2
- MORC2 | c.778C>T p.H260Y (on ENST00000397641 / NM_001303256.3; = p.H198Y on NM_014941.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs755209985, COSV99310113; called by muse, mutect2, varscan2
- MSH4 | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV99592050; called by muse, mutect2, varscan2
- MSL2 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100017580; called by muse, mutect2, varscan2
- MUC16 | c.39053C>A p.T13018N | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101200472; called by muse, mutect2, varscan2
- MUC5B | c.9379T>A p.S3127T | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV101500533; called by muse, mutect2, varscan2
- MYH7B | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV99483012; called by muse, mutect2, varscan2
- NBR1 | c.564G>C p.L188F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100357915; called by muse, mutect2, varscan2
- NCAM2 | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV99523948; called by muse, mutect2
- NCAPD3 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV101592980; called by muse, mutect2, varscan2
- NLRP4 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100016661; called by muse, mutect2, varscan2
- NLRP4 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100016664; called by muse, mutect2, varscan2
- OR10K1 | c.571C>G p.H191D | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.243); catalogued as COSV99193768; called by muse, mutect2, varscan2
- OR2M4 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.259); catalogued as COSV100141373; called by muse, mutect2, varscan2
- OR2T12 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100527879; called by muse, mutect2, varscan2
- OR5D16 | c.538T>A p.F180I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.842); catalogued as COSV101004055; called by muse, mutect2, varscan2
- OR6A2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60264794; called by muse, mutect2, varscan2
- OR6B2 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99401584; called by mutect2, varscan2
- OR6M1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.251); catalogued as rs776573710, COSV58432692; called by muse, mutect2, varscan2
- OR8H1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV57293201; called by muse, mutect2, varscan2
- OSBPL6 | c.1395+1G>T p.X465_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV51915707; called by muse, mutect2, varscan2
- OTOGL | c.4496G>T p.W1499L (on ENST00000547103; = p.W1490L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100087495; called by muse, mutect2, varscan2
- PAK5 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100781517; called by muse, mutect2, varscan2
- PCDHA6 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100972421; called by muse, mutect2, varscan2
- PCDHA7 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 138/163 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV65344513; called by muse, mutect2, varscan2
- PCDHAC2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.456); catalogued as COSV99151158; called by muse, mutect2, varscan2
- PI15 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs895589209, COSV52639869, COSV99478124; called by muse, mutect2, varscan2
- PI15 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV52640034, COSV99478125; called by muse, mutect2, varscan2
- PI4KA | c.6163A>T p.K2055* | Nonsense Mutation (SNP) | VAF 37/88 reads (42%) | catalogued as COSV99747252; called by muse, mutect2, varscan2
- PLD5 | c.400C>A p.Q134K (on ENST00000442594; = p.Q72K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.444); catalogued as COSV100141452, COSV59160146; called by mutect2, varscan2
- PLPPR1 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs754925689, COSV100883406; called by muse, mutect2, varscan2
- PLSCR2 | c.865-1G>T p.X289_splice (on ENST00000497985 / NM_001199978.1; = p.X216_splice on NM_020359.2) | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100367809; called by muse, mutect2, varscan2
- PLXNA2 | c.5129C>T p.P1710L | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65445333; called by muse, mutect2, varscan2
- PPP1R17 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as COSV100566420; called by muse, mutect2, varscan2
- PPP1R9A | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99196407; called by muse, mutect2, varscan2
- PRR23B | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as rs750250049, COSV100272146, COSV61493913; called by muse, mutect2, varscan2
- PSMA8 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100378986, COSV57604180; called by muse, mutect2, varscan2
- PTDSS1 | c.272-2A>T p.X91_splice | Splice Site (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100428778; called by muse, mutect2, varscan2
- PTGIR | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as rs202009923, COSV99355017; called by muse, mutect2, varscan2
- PTPN12 | c.137A>T p.K46M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99950497; called by muse, mutect2, varscan2
- PYHIN1 | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63721912; called by muse, mutect2, varscan2
- RABGGTA | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.17); catalogued as rs774100217, COSV99397738; called by muse, mutect2, varscan2
- RITA1 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100232429; called by muse, varscan2
- RPA4 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61293603; called by muse, mutect2, varscan2
- RPH3A | c.590C>G p.P197R (on ENST00000389385 / NM_001143854.2; = p.P193R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV101231851; called by muse, mutect2, varscan2
- RYR1 | c.7885G>A p.D2629N | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1400840609, COSV100616264; called by muse, mutect2, varscan2
- SALL1 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1399094688, COSV99175183; called by muse, mutect2, varscan2
- SCN10A | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101479462; called by muse, mutect2, varscan2
- SCN1A | c.3572G>T p.C1191F (on ENST00000303395 / NM_001202435.3; = p.C1180F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV100321146; called by muse, mutect2, varscan2
- SECISBP2 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100068869; called by muse, mutect2, varscan2
- SEMA5A | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101228524, COSV66786713; called by muse, mutect2, varscan2
- SEPTIN5 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100820430; called by muse, mutect2, varscan2
- SH3BP2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.43); catalogued as COSV100696989; called by muse, mutect2, varscan2
- SLC12A3 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99343937, COSV99344468; called by muse, mutect2, varscan2
- SLC22A2 | c.1442C>A p.T481K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100871008; called by muse, mutect2, varscan2
- SLC36A3 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100077721, COSV100077870, COSV58857616; called by muse, mutect2, varscan2
- SLC51A | c.450C>A p.D150E | Missense Mutation (SNP) | VAF 104/533 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99580325; called by muse, varscan2
- SLCO1C1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV56871867, COSV56872540; called by muse, mutect2, varscan2
- SLITRK2 | c.1551G>C p.Q517H | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.933); catalogued as COSV100157951; called by muse, mutect2, varscan2
- SLITRK2 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100157953; called by muse, mutect2, varscan2
- SOCS4 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs201252248, COSV100216249, COSV59460682; called by muse, mutect2, varscan2
- SOX11 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100431281; called by muse, mutect2, varscan2
- SPAG9 | c.1664+1G>T p.X555_splice (on ENST00000262013 / NM_001130528.3; = p.X541_splice on NM_003971.6) | Splice Site (SNP) | VAF 11/12 reads (92%) | catalogued as COSV100005477; called by muse, mutect2, varscan2
- SPATA31D1 | c.2370G>C p.E790D | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.407); catalogued as COSV100782904, COSV61200093; called by muse, mutect2
- SPEN | c.8204C>T p.T2735I | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs754688541, COSV101005405; called by muse, mutect2, varscan2
- SPTBN4 | c.4051G>A p.A1351T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100151478; called by muse, mutect2, varscan2
- SQSTM1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/10 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as rs1302810798, COSV62434198; called by muse, mutect2
- SSRP1 | c.1449C>G p.N483K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53480680; called by muse, mutect2, varscan2
- STEAP4 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100112638; called by muse, mutect2, varscan2
- SULF1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99483598; called by muse, mutect2, varscan2
- SYTL2 | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100314534; called by muse, mutect2, varscan2
- TAAR5 | c.959T>G p.L320R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99236950; called by muse, mutect2, varscan2
- TBX15 | c.1437T>A p.Y479* (on ENST00000369429 / NM_001330677.2; = p.Y373* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 24/37 reads (65%) | catalogued as COSV99254406; called by muse, mutect2, varscan2
- TEKT5 | c.148T>A p.W50R | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99296253; called by muse, mutect2, varscan2
- TEX13A | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 123/157 reads (78%) | SIFT tolerated (0.38); PolyPhen benign (0.209); catalogued as COSV100781591; called by muse, mutect2, varscan2
- TMEM132D | c.2148T>A p.S716R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101242960; called by muse, mutect2, varscan2
- TMEM139 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1178126903, COSV100131132; called by muse, mutect2, varscan2
- TMEM255A | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550451; called by muse, mutect2, varscan2
- TPRX1 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100445784; called by muse, mutect2, varscan2
- TROAP | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV99226928; called by muse, mutect2, varscan2
- TRPC5 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 106/139 reads (76%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.5); catalogued as COSV99461748; called by muse, mutect2, varscan2
- TSHZ2 | c.1854T>A p.S618R | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV100296400; called by muse, mutect2, varscan2
- TSPAN4 | c.590G>C p.W197S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100059973; called by muse, mutect2, varscan2
- TTC39B | c.1764G>T p.K588N | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.412); catalogued as COSV99895644; called by muse, mutect2, varscan2
- TTN | c.67612G>C p.V22538L (on ENST00000591111; = p.V15114L on NM_003319.4) | Missense Mutation (SNP) | VAF 109/293 reads (37%) | PolyPhen benign (0.001); catalogued as COSV100620518; called by muse, mutect2, varscan2
- TTN | c.53903C>G p.P17968R (on ENST00000591111; = p.P10544R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV100620522, COSV59867001; called by muse, mutect2, varscan2
- TTN | c.20971G>T p.A6991S (on ENST00000591111; = p.A6064S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | PolyPhen benign (0.223); catalogued as COSV100620524; called by muse, mutect2, varscan2
- TTN | c.6888A>T p.E2296D (on ENST00000591111; = p.E2250D on NM_003319.4) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | PolyPhen benign (0.013); catalogued as COSV100620525; called by muse, mutect2, varscan2
- TTN | c.4510A>G p.K1504E (on ENST00000591111; = p.K1458E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | PolyPhen probably damaging (0.994); catalogued as COSV100620526; called by muse, mutect2, varscan2
- UMODL1 | c.199T>C p.W67R | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1183524597, COSV101253430; called by muse, mutect2, varscan2
- VCAN | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99426495; called by muse, mutect2, varscan2
- VCAN | c.8909G>T p.G2970V | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54118571, COSV99426498; called by muse, mutect2, varscan2
- VN1R2 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100448063; called by muse, mutect2, varscan2
- VTN | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99879748; called by muse, mutect2, varscan2
- WDR64 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs947588343, COSV100843885, COSV63795261; called by muse, mutect2, varscan2
- WDR73 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV100822100; called by muse, mutect2
- WIZ | c.4541C>G p.S1514C (on ENST00000673675 / NM_001371589.1; = p.S419C on NM_021241.3) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs892734117, COSV99653489; called by muse, mutect2, varscan2
- WNT10B | c.581G>T p.W194L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56404891, COSV99975980; called by muse, mutect2, varscan2
- WNT10B | c.580T>A p.W194R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99975982; called by muse, mutect2, varscan2
- WNT5B | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148752; called by muse, mutect2
- XKR4 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100533193; called by muse, mutect2, varscan2
- ZBTB20 | c.1467G>A p.M489I (on ENST00000474710 / NM_001164342.2; = p.M416I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100614333; called by muse, mutect2, varscan2
- ZBTB26 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV101021119; called by muse, mutect2, varscan2
- ZEB1 | c.2799G>T p.E933D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100314660; called by mutect2, varscan2
- ZEB2 | c.2209G>T p.D737Y | Missense Mutation (SNP) | VAF 92/179 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as CD072519, COSV100356438; called by muse, mutect2, varscan2
- ZER1 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as COSV99402227; called by muse, mutect2, varscan2
- ZNF335 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV100533185; called by muse, mutect2
- ZNF676 | c.767C>T p.P256L (on ENST00000650058; = p.P224L on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.402); catalogued as COSV101236266; called by muse, mutect2, varscan2
- ZP2 | c.1373A>C p.E458A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99559627; called by muse, mutect2, varscan2
- ADAMTS9 | c.3909del p.L1304* | Frame Shift Del (DEL) | VAF 67/111 reads (60%) | called by mutect2, pindel, varscan2
- ADCY8 | c.2217G>A p.M739I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- DACT1 | c.1775del p.Q592Rfs*100 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- DENND1B | c.574del p.E192Nfs*8 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- GGT1 | c.382+2T>A p.X128_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2
- IGHV3-66 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- KLHL30 | c.364del p.C122Afs*79 | Frame Shift Del (DEL) | VAF 9/12 reads (75%) | called by mutect2, varscan2
- MGAM | c.2345del p.P782Lfs*14 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- OR11H6 | c.453del p.S152Pfs*3 | Frame Shift Del (DEL) | VAF 57/140 reads (41%) | called by mutect2, pindel, varscan2
- PRSS38 | c.118_133del p.N40* | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- RAVER2 | c.1068del p.L357Yfs*24 | Frame Shift Del (DEL) | VAF 60/94 reads (64%) | called by mutect2, pindel, varscan2
- RC3H2 | c.466dup p.R156Pfs*98 | Frame Shift Ins (INS) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- REV3L | c.5974dup p.I1992Nfs*33 | Frame Shift Ins (INS) | VAF 36/70 reads (51%) | called by mutect2, varscan2
- RPL22L1 | c.24del p.K8Nfs*17 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | called by mutect2, pindel*, varscan2
- RYR2 | c.10840C>A p.H3614N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ABCB1 | c.3363C>T p.I1121= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV99713534; called by muse, mutect2, varscan2
- ABCB4 | c.3273G>A p.G1091= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs749647874, COSV99710821; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3327C>A p.T1109= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV54464582, COSV99719915; called by muse, mutect2, varscan2
- ALOX12B | c.1794C>G p.S598= | Silent (SNP) | VAF 165/202 reads (82%) | catalogued as COSV100047437; called by muse, mutect2, varscan2
- AMER2 | c.1653C>T p.S551= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as rs375589201, COSV100766318; called by muse, mutect2, varscan2
- ANGPTL4 | c.822C>A p.A274= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV100035183; called by muse, mutect2, varscan2
- ATP13A5 | c.1665C>A p.G555= | Silent (SNP) | VAF 178/600 reads (30%) | catalogued as COSV60868765; called by muse, varscan2
- BIRC3 | c.678G>C p.L226= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV99680058; called by muse, mutect2, varscan2
- CCDC22 | c.105A>G p.V35= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV100545089; called by muse, mutect2, varscan2
- CFAP251 | c.3330C>G p.S1110= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV56608850, COSV99996277; called by muse, mutect2, varscan2
- CSRNP3 | c.294T>C p.H98= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100086040; called by muse, mutect2, varscan2
- DCAF12L1 | c.42C>A p.P14= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV100948367; called by muse, mutect2, varscan2
- DCAF4L2 | c.243C>A p.T81= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV100151063; called by muse, mutect2, varscan2
- DMXL1 | c.4182T>C p.N1394= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV100224399; called by muse, mutect2, varscan2
- DNAH9 | c.12042C>A p.I4014= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV99306786; called by muse, mutect2, varscan2
- EBF2 | c.75G>T p.S25= | Silent (SNP) | VAF 65/161 reads (40%) | catalogued as COSV101282243; called by muse, mutect2, varscan2
- ENPEP | c.660C>A p.T220= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as COSV99487817; called by muse, mutect2, varscan2
- ENPP3 | c.906G>T p.L302= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100717673; called by muse, mutect2, varscan2
- FHOD1 | c.2874G>A p.L958= | Silent (SNP) | VAF 52/73 reads (71%) | catalogued as COSV99264286; called by muse, mutect2, varscan2
- FSHR | c.18C>A p.V6= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100437567; called by muse, mutect2, varscan2
- GALR3 | c.90G>A p.L30= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as COSV99968051; called by muse, mutect2, varscan2
- GRM8 | c.2019C>A p.I673= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV100284352, COSV58814461; called by muse, mutect2, varscan2
- GYPE | c.186G>T p.V62= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100679367; called by muse, mutect2, varscan2
- HIF1A | c.189C>T p.T63= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV100049070; called by muse, mutect2, varscan2
- ITPR2 | c.7446C>A p.L2482= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as COSV67272377; called by muse, mutect2, varscan2
- KCNJ3 | c.816C>T p.H272= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs766872166, COSV99716132; called by muse, mutect2, varscan2
- KCNK17 | c.930G>A p.E310= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs950949329, COSV100950241; called by muse, mutect2, varscan2
- KRT16 | c.675G>T p.R225= | Silent (SNP) | VAF 71/166 reads (43%) | catalogued as COSV100052972; called by muse, mutect2, varscan2
- LARGE1 | c.1260C>T p.P420= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100505898; called by muse, mutect2, varscan2
- LRP1 | c.9840C>T p.V3280= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as COSV99676481; called by muse, mutect2, varscan2
- LRRC7 | c.3642C>T p.H1214= (on ENST00000651989 / NM_001370785.2; = p.H1181= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV99228093; called by muse, mutect2, varscan2
- METTL17 | c.681A>T p.A227= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100228293; called by muse, mutect2, varscan2
- MGAM | c.1794C>A p.A598= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV101527595; called by muse, mutect2, varscan2
- MYLK4 | c.102G>T p.V34= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs762308686, COSV99193850; called by muse, mutect2, varscan2
- NRXN3 | c.1674G>T p.S558= (on ENST00000557594 / NM_001272020.2; = p.S982= on NM_004796.6) | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs766551508, COSV55314015, COSV55321750, COSV99820207; called by muse, mutect2, varscan2
- OCA2 | c.1050G>A p.V350= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as COSV100668212; called by muse, mutect2, varscan2
- OR11A1 | c.624C>A p.L208= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV101010717; called by muse, mutect2, varscan2
- OR12D3 | c.300C>T p.H100= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV101011370; called by muse, mutect2, varscan2
- OR2AT4 | c.42C>G p.P14= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100532375, COSV59406566; called by muse, mutect2, varscan2
- OR2B6 | c.546T>A p.P182= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs763989384, COSV99773802; called by muse, mutect2, varscan2
- OR4A5 | c.333C>T p.F111= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1156629694, COSV60521461, COSV60522988; called by muse, mutect2, varscan2
- OR5T3 | c.714G>A p.L238= | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as rs184740259, COSV100282862; called by muse, mutect2, varscan2
- OR6K2 | c.42C>T p.F14= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100656831; called by muse, mutect2, varscan2
- OR6V1 | c.250T>C p.L84= | Silent (SNP) | VAF 110/228 reads (48%) | catalogued as rs757225070, COSV101389441; called by muse, mutect2, varscan2
- OVOL2 | c.447C>T p.C149= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99602528; called by muse, mutect2, varscan2
- PAX1 | c.900G>T p.T300= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV101270337, COSV68271516; called by muse, mutect2, varscan2
- PCDH9 | c.2916C>A p.T972= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as COSV100122013; called by muse, mutect2, varscan2
- PMP22 | c.204C>T p.T68= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV100396973; called by muse, mutect2, varscan2
- PNLDC1 | c.1449C>A p.I483= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV99277658; called by muse, mutect2, varscan2
- PPP2R2D | c.910C>A p.R304= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV70778758, COSV70778965; called by muse, mutect2, varscan2
- SEMA5B | c.369C>A p.A123= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99532493; called by muse, mutect2, varscan2
- SHISA2 | c.522G>T p.R174= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as rs1316204339, COSV100096323, COSV100096510; called by muse, mutect2, varscan2
- SLC25A41 | c.435C>T p.F145= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100383105; called by muse, mutect2, varscan2
- SLC37A4 | c.75C>T p.Y25= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1018110428, COSV100421564; called by muse, mutect2, varscan2
- SLC44A5 | c.846A>T p.I282= | Silent (SNP) | VAF 55/65 reads (85%) | catalogued as COSV100902229; called by muse, mutect2, varscan2
- SMYD2 | c.399G>A p.E133= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as COSV100873262; called by muse, mutect2, varscan2
- STAB2 | c.1800C>A p.A600= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV101185811, COSV101186139; called by muse, mutect2, varscan2
- STAT5B | c.522C>A p.I174= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99511102; called by muse, mutect2, varscan2
- TBK1 | c.744A>C p.G248= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100538249; called by muse, mutect2, varscan2
- TLN2 | c.109C>A p.R37= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV100169537; called by muse, mutect2, varscan2
- TMEM43 | c.333G>A p.P111= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as rs774276092, COSV60147063; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TMEM72 | c.603C>A p.P201= | Silent (SNP) | VAF 63/201 reads (31%) | catalogued as COSV101273550; called by muse, mutect2, varscan2
- TNN | c.2043T>G p.G681= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV99512405; called by muse, mutect2, varscan2
- TRMT61B | c.435T>C p.T145= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100066686; called by muse, mutect2
- VPS13B | c.4530C>T p.A1510= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100662634; called by mutect2, varscan2
- VPS41 | c.666C>G p.L222= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV99731117; called by muse, mutect2, varscan2
- WDR88 | c.213G>T p.L71= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV99404168; called by muse, mutect2, varscan2
- ZFHX4 | c.2529G>A p.Q843= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99264948; called by muse, mutect2, varscan2
- ABCC10 | c.-12+103G>T | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99767586; called by muse, varscan2
- AC073310.1 | n.678G>A | RNA (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- BLACAT1 | c.-36-7286dup | Intron (INS) | VAF 59/156 reads (38%) | called by mutect2, pindel, varscan2
- BMP1 | c.731-255G>T | Intron (SNP) | VAF 91/220 reads (41%) | catalogued as rs771054164, COSV100109831; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-151G>T | Intron (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- C10orf71 | c.*138G>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100110387; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+181G>T | Intron (SNP) | VAF 57/138 reads (41%) | catalogued as COSV99180718; called by muse, mutect2, varscan2
- FAM74A3 | n.356G>C | RNA (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- MAPK8 | c.688+410G>C | Intron (SNP) | VAF 71/134 reads (53%) | catalogued as rs779762614; called by muse, mutect2, varscan2
- MIR758 | n.74C>A | RNA (SNP) | VAF 65/126 reads (52%) | called by muse, mutect2, varscan2
- NEDD8 | chr14:24213531 G>A | 3'Flank (SNP) | VAF 34/74 reads (46%) | catalogued as rs746915038, COSV99164642; called by muse, mutect2, varscan2
- OR2W5 | n.722C>T | RNA (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- TRIM24 | c.*929G>A | 3'UTR (SNP) | VAF 34/64 reads (53%) | catalogued as rs749136562, COSV100631072; called by muse, mutect2, varscan2
- Y_RNA | chr7:75514672 T>A | 5'Flank (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
